Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6499, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6499-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

TCGA - G9 - 6499

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES

Received fresh for frozen section is a 6.5 x 4.5 x 1.0cm aggregate of fibrofatty tissue. Dissection reveals 9 possible lymph nodes ranging from 0.7cm to 2.4cm. Toto FSA1-FSA4.

B. LEFT PELVIC LYMPH NODES

Received fresh for frozen section is a 6.0 x 3.0 x 0.6cm aggregate of fibrofatty tissue. Dissection reveals 4 possible lymph nodes ranging from 0.7cm to 2.9cm. Toto FSB1-FSB3.

C. PROSTATE

Received fresh is a 54-g resected prostate gland measuring 4.7 cm from anterior to posterior, 4.5 cm from left to right, and 2.8 cm from superior to inferior. The capsule is smooth, red, and intact. Specimen is inked as follows: anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, and posterior-black. Specimen is serially sectioned from apex to base revealing a well-circumscribed tan nodule measuring 1.3 cm, located in the right mid prostate. After removal of the apex and base, the prostate proper weighs 25 g. Alternating levels are submitted for tissue procurement. The right seminal vesicle is 4.7 x 3.2 x 1.2 cm and the left is 3.8 x 3.2 x 1.1 cm; they have a cystic tan appearance. The right vas deferens is 4.7 cm in length and 0.7 cm in width and the left vas deferens is 3.7 cm in length by 0.6 cm in width; they have a tubular tan appearance. Specimen is submitted entirely:

- C1: right apex, perpendicular sections
- C2: left apex, perpendicular sections
- C3: level 1, anterior and right lateral capsule
- C4: level 1, posterior and left lateral capsule
- C5: level 2, right anterior
- C6: level 2, right posterior
- C7: level 2, left anterior
- C8: level 2, left posterior
- C9: level 3, anterior and right lateral capsule
- C10: level 3, posterior and left lateral capsule
- C11-C12: right mid base
- C13-C14: left mid base
- C15-C16: right lateral base
- C17-C18: left lateral base
- C19: base of right seminal vesicle and vas deferens
- C20: base of left seminal vesicle and vas deferens
- C21: right seminal vesicle
- C22: right vas deferens
- C23: right seminal vesicle left seminal vesicle and vas deferens

DIAGNOSIS:

A. LYMPH NODES, RIGHT PELVIS, RESECTION:

- NINE LYMPH NODES, NEGATIVE FOR METASTASES (0/9).

B. LYMPH NODE, LEFT PELVIS, RESECTION:

- FOUR LYMPH NODES, NEGATIVE FOR METASTASES (0/4).

C. PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON'S GRADE 4+5 (9/10), INVOLVING ABOUT 30% OF PROSTATE VOLUME, PRESENT IN BOTH LOBES
- FOCAL PERIPROSTATIC INVOLVEMENT PRESENT
- SEMINAL VESICLES AND VAS DEFERENSES, NO TUMOR SEEN

[page 2 of 2]
-
- SURGICAL RESECTION MARGINS NEGATIVE FOR TUMOR
- SEE SYNOPTIC REPORT AND SEE NOTE.

NOTE: Dr. concurs on the Gleason's grade and periprostatic fat involvement.

SYNOPTIC REPORT - PROSTATE GLAND

Location: Left
Right
Posterior lateral
Apical
Basal
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 30%
Gleason Grade/Sum:: Grade 4 + 5 , Sum 9
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: Yes
Details: focal
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Lymph Nodes: Negative Right 0 / 9 Left 0 / 4
Other Pathologic Findings: BPH
Pathological Staging (pTNM): T 3a N 0 M x

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer.

INTRAOPERATIVE CONSULTATION:

FSA1-FSA4: No carcinoma identified in nine lymph nodes. Diagnosis called to Dr. at by Dr.
FSB1-FSB3: No carcinoma identified in four lymph nodes. Diagnosis called to Dr. at by Dr.
***Evaluation was technically difficult due to fatty infiltration of the lymph nodes.

Source: NCI Genomic Data Commons file 74e91d19-a9a5-4bf0-8b41-598facc49b04 (TCGA-G9-6499.8E1D4212-B252-4019-B188-3CDD60BE733D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).